Somatic mutation profile of cancer-model specimen HCM-CSHL-0180-C25-85B (3D Organoid, passage 9; aliquot HCM-CSHL-0180-C25-85B-01D-A79L-36), derived from the primary tumor of HCMI case HCM-CSHL-0180-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.0 years (23,371 days).
Specimen HCM-CSHL-0180-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5db9ffd-cc99-4be9-9c3e-336ef3ca56b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0180-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0180-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb21b7ae-0664-43e1-8b24-5f699628e3f3

The open-access MAF lists 83 somatic variants for this specimen: 62 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 17, Intron 3, Nonsense Mutation 2, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 164/316 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455dup p.P153Afs*28 | Frame Shift Ins (INS) | VAF 273/390 reads (70%) | catalogued as rs730882019, COSV53468298, COSV99394349; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADCY1 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 126/260 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs1326557048, COSV52032152; called by muse, mutect2, varscan2
- ADRA1D | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 341/707 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs538270081, COSV65240389; called by muse, mutect2, varscan2
- AXL | c.1828C>T p.R610* (on ENST00000301178 / NM_021913.5; = p.R601* on NM_001699.6) | Nonsense Mutation (SNP) | VAF 188/414 reads (45%) | catalogued as rs758985963, COSV56566085; called by muse, mutect2, varscan2
- C7orf61 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 309/590 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as rs370137741; called by muse, mutect2, varscan2
- CACNA1F | c.5369G>A p.R1790H | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs781946990, COSV59905762; called by muse, mutect2, varscan2
- CACNA1G | c.3015C>A p.F1005L | Missense Mutation (SNP) | VAF 80/446 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV61727629, COSV61730572; called by muse, mutect2, varscan2
- CDK6 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 155/345 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV56006892; called by muse, mutect2, varscan2
- COL24A1 | c.2230G>A p.G744R | Missense Mutation (SNP) | VAF 143/290 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65306064; called by muse, mutect2, varscan2
- CSMD2 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 278/285 reads (98%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs774023508, COSV53879951, COSV99592538; called by muse, varscan2
- FGFR3 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 179/179 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs769591617, COSV53404184; called by muse, mutect2, varscan2
- FOXL3 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 202/394 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72563063; called by muse, varscan2
- GOLGA6L6 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 223/1579 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1174035987; called by muse, mutect2, varscan2
- INSRR | c.2970T>G p.F990L | Missense Mutation (SNP) | VAF 289/510 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100947344; called by muse, mutect2, varscan2
- KCNA6 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 208/479 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54974128, COSV99768741; called by muse, varscan2
- KCNF1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 250/545 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1313019497; called by muse, mutect2, varscan2
- KCNH4 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 197/402 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs751569305, COSV52920746; called by muse, mutect2, varscan2
- KHDRBS3 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 155/329 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs200509558, COSV63414522; called by muse, mutect2, varscan2
- MGAT5B | c.1898G>A p.R633Q (on ENST00000569840 / NM_001199172.2; = p.R631Q on NM_144677.3) | Missense Mutation (SNP) | VAF 229/489 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56927723; called by muse, mutect2, varscan2
- MROH9 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 124/248 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1427137680; called by muse, mutect2, varscan2
- NAPA | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 217/444 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs774144496; called by muse, mutect2, varscan2
- PLSCR2 | c.497C>A p.P166Q (on ENST00000497985 / NM_001199978.1; = p.P93Q on NM_020359.2) | Missense Mutation (SNP) | VAF 166/322 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100367854; called by muse, mutect2, varscan2
- PRKAG3 | c.143G>C p.R48T | Missense Mutation (SNP) | VAF 233/457 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.111); catalogued as COSV52103716, COSV52103936; called by muse, mutect2, varscan2
- PXDNL | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 123/240 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100684251, COSV62478353; called by muse, mutect2, varscan2
- RPGRIP1 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 259/267 reads (97%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs980350108, COSV52844460, COSV52846680; called by muse, mutect2, varscan2
- SHCBP1L | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 238/407 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs757649009, COSV62353893; called by muse, mutect2
- SIGLEC14 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 231/582 reads (40%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.587); catalogued as rs753560578, COSV55777551, COSV55779228; called by muse, mutect2, varscan2
- SLC5A11 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 84/529 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs767240476, COSV61740557; called by muse, mutect2, varscan2
- STAG3 | c.3047C>T p.S1016F | Missense Mutation (SNP) | VAF 120/292 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57930050; called by muse, mutect2, varscan2
- TMEM151B | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 191/434 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1445302149; called by muse, mutect2, varscan2
- TNIP3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 75/75 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.36); catalogued as rs746782978, COSV50246703; called by muse, mutect2, varscan2
- TNR | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 244/476 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs138654492; called by muse, mutect2, varscan2
- UNC79 | c.5780G>A p.R1927Q (on ENST00000393151 / NM_001346218.2; = p.R1750Q on NM_020818.5) | Missense Mutation (SNP) | VAF 28/559 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs770522803, COSV56383061; called by muse, mutect2
- BCAR3 | c.2296G>T p.A766S | Missense Mutation (SNP) | VAF 146/283 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDH4 | c.2258T>A p.V753D | Missense Mutation (SNP) | VAF 175/356 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CEP350 | c.2284C>T p.L762F | Missense Mutation (SNP) | VAF 50/436 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- CHRM5 | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 155/418 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNNM4 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 316/643 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COBL | c.2966T>C p.V989A | Missense Mutation (SNP) | VAF 207/466 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- DHX37 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 180/365 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FNDC1 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 334/645 reads (52%) | called by muse, mutect2, varscan2
- KALRN | c.3979C>T p.H1327Y | Missense Mutation (SNP) | VAF 154/351 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KIR2DL4 | c.230G>C p.S77T (on ENST00000396284; = p.S38T on NM_001080770.2) | Missense Mutation (SNP) | VAF 42/678 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.655); called by muse, mutect2
- LMAN2 | c.46T>C p.C16R | Missense Mutation (SNP) | VAF 387/831 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MCPH1 | c.2036T>C p.V679A | Missense Mutation (SNP) | VAF 28/550 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- MUSK | c.2387_2389del p.F796del | In Frame Del (DEL) | VAF 282/292 reads (97%) | called by pindel, varscan2
- NKX6-2 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 426/871 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLRP8 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 69/342 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- PNPLA5 | c.83_98del p.T28Sfs*49 | Frame Shift Del (DEL) | VAF 220/590 reads (37%) | called by pindel, varscan2
- RSPH10B2 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 146/302 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SCFD2 | c.155C>G p.P52R | Missense Mutation (SNP) | VAF 329/329 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SDK1 | c.3892A>G p.T1298A | Missense Mutation (SNP) | VAF 221/440 reads (50%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3TC2 | c.2720G>A p.C907Y | Missense Mutation (SNP) | VAF 225/474 reads (47%) | SIFT tolerated (0.86); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SHCBP1L | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STARD9 | c.3877C>T p.L1293F | Missense Mutation (SNP) | VAF 59/560 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TRPM2 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 123/595 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TSSK1B | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 42/644 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.438); called by muse, mutect2
- TTN | c.18168G>C p.E6056D (on ENST00000591111; = p.E5129D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/368 reads (45%) | PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF234 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF865 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 26/974 reads (3%) | SIFT tolerated, low confidence (0.13); called by muse, mutect2
- ZSWIM1 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 28/768 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCA13 | c.12135C>T p.A4045= | Silent (SNP) | VAF 302/627 reads (48%) | catalogued as rs756550869, COSV71293444; called by muse, mutect2
- CACNB4 | c.1191G>A p.A397= | Silent (SNP) | VAF 191/436 reads (44%) | catalogued as rs369276166; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- CEP295NL | c.156C>T p.F52= | Silent (SNP) | VAF 288/557 reads (52%) | catalogued as rs937177060; called by muse, mutect2, varscan2
- CYP1A1 | c.858T>C p.I286= | Silent (SNP) | VAF 222/222 reads (100%) | called by muse, mutect2, varscan2
- DYNC2I2 | c.81G>T p.A27= | Silent (SNP) | VAF 556/557 reads (100%) | catalogued as rs769249867; called by muse, mutect2, varscan2
- FOXI2 | c.99C>T p.G33= | Silent (SNP) | VAF 374/805 reads (46%) | called by muse, mutect2, varscan2
- GRIP1 | c.879C>T p.G293= | Silent (SNP) | VAF 128/257 reads (50%) | catalogued as rs746461059, COSV54017194; called by muse, mutect2, varscan2
- GRM6 | c.816C>T p.N272= | Silent (SNP) | VAF 245/506 reads (48%) | catalogued as rs1046529474, COSV51441167; called by muse, mutect2, varscan2
- HERC1 | c.10176G>A p.V3392= | Silent (SNP) | VAF 231/372 reads (62%) | catalogued as rs761597330; called by muse, mutect2, varscan2
- JPH1 | c.528C>G p.L176= | Silent (SNP) | VAF 387/725 reads (53%) | catalogued as rs773219532; called by muse, mutect2, varscan2
- LHX5 | c.1044G>A p.P348= | Silent (SNP) | VAF 283/594 reads (48%) | called by muse, mutect2, varscan2
- LRP2 | c.13854G>A p.S4618= | Silent (SNP) | VAF 219/466 reads (47%) | catalogued as rs756813419; called by muse, mutect2, varscan2
- NPHP4 | c.2358C>T p.V786= | Silent (SNP) | VAF 270/518 reads (52%) | catalogued as rs371647995; ClinVar: likely benign; called by muse, mutect2, varscan2
- ROBO4 | c.909C>T p.A303= | Silent (SNP) | VAF 302/903 reads (33%) | catalogued as rs572632935; called by muse, mutect2, varscan2
- SHE | c.285C>A p.G95= | Silent (SNP) | VAF 407/820 reads (50%) | called by muse, mutect2, varscan2
- USP24 | c.1665C>T p.L555= | Silent (SNP) | VAF 131/301 reads (44%) | catalogued as COSV53774523; called by muse, mutect2, varscan2
- UTP14C | c.702C>A p.S234= | Silent (SNP) | VAF 20/662 reads (3%) | called by muse, mutect2
- DNAJB6 | c.691+9C>A | Intron (SNP) | VAF 76/511 reads (15%) | called by muse, mutect2, varscan2
- KCNAB2 | c.1014+60C>T | Intron (SNP) | VAF 349/750 reads (47%) | called by muse, mutect2
- MUCL3 | c.946+245A>G | Intron (SNP) | VAF 341/685 reads (50%) | called by muse, mutect2, varscan2
- PLEKHG4B | chr5:139560 G>A | 5'Flank (SNP) | VAF 346/560 reads (62%) | catalogued as rs761612717; called by muse, mutect2
